Somatic mutation profile of tumor specimen 0DDZ6Y from CCDI case PBBPGU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.3 years (5,578 days).
Specimen 0DDZ6Y: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3ecb0c4-7795-4a8f-84b9-61a90787a0bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDZ5Z (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/134d682b-b830-446c-9d79-5dca1c272c7c

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 84/1052 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2
- MRGPRE | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 30/329 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.391); catalogued as rs754926111, COSV67745840; called by muse, mutect2
- SCN11A | c.4075G>A p.V1359M | Missense Mutation (SNP) | VAF 74/902 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as rs777323474, COSV56567930, COSV56568066; ClinVar: uncertain significance; called by muse, mutect2
- HDAC4 | c.1896C>T p.S632= | Silent (SNP) | VAF 39/378 reads (10%) | called by muse, mutect2, varscan2
- PCDHB13 | c.2112G>A p.S704= | Silent (SNP) | VAF 36/266 reads (14%) | catalogued as COSV53399055; called by muse, mutect2, varscan2
- GLDC | c.2570-78A>T | Intron (SNP) | VAF 27/279 reads (10%) | called by muse, mutect2
